Gene-level copy-number profile of tumor specimen HCM-BROD-0235-C16-06A from HCMI case HCM-BROD-0235-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 50.7 years (18,528 days).
Specimen HCM-BROD-0235-C16-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 04e66b24-7ea0-44ad-85f3-9cf360f80274.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0235-C16-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,737 have no estimate.
https://portal.gdc.cancer.gov/files/02b209b2-cfbf-40eb-a2bb-5bf1d983aaa8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 288; copy number 2: 9,825; copy number 3: 24,478; copy number 4: 19,861; copy number 5: 2,672; copy number 6: 1,214; copy number 7: 130; copy number 8: 12; copy number 9: 33; copy number 10: 47; copy number 11: 3; copy number 12: 61; copy number 13: 158; copy number 14: 76; copy number 20: 9; copy number 32: 11.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:177,686,673–177,691,068, 1 gene: AC103879.1.
- chr8:12,333,644–12,388,296, 6 genes: RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 540 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–90,367,699, 43 genes, copy number 7–9: IGKV1-39, IGKV2-40, 5S_rRNA, IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7.
- chr7:84,847,877–86,217,733, 11 genes, copy number 9: AC093716.1, HMGN2P11, AC074183.2, AC074183.1, HNRNPA1P8, SEMA3D, HSPA8P16, DYNLL1P7, LINC00972, AC092013.1, SOCS5P1.
- chr7:89,443,946–93,574,730, 61 genes, copy number 9–14 (broad region; genes not listed).
- chr7:93,890,913–102,283,958, 238 genes, copy number 10–13 (within-gene range 3–13) (broad region; genes not listed).
- chr8:122,485,194–122,733,804, 1 gene, copy number 9 (within-gene range 6–9): LINC01151.
- chr8:122,671,291–124,260,752, 48 genes, copy number 7–10: AC100872.1, AC100872.2, CDK5P1, AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1, FER1L6, AC090753.1, FER1L6-AS1, AC100871.2, FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P.
- chr8:124,811,042–127,482,139, 43 genes, copy number 7–8: AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2.
- chr8:127,735,434–128,564,679, 14 genes, copy number 7: MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824.
- chr8:131,129,761–133,814,537, 37 genes, copy number 7: AC087341.1, AC104257.1, SNORA72, AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3.
- chr9:42,566,679–42,569,353, 2 genes, copy number 20: BX088651.4, BX088651.1.
- chr16:32,649,193–32,678,831, 5 genes, copy number 7: AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3.
- chr19:13,206,442–14,213,323, 36 genes, copy number 9–32 (within-gene range 3–32): CACNA1A, CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1, DCAF15, RFX1, AC022098.4, RLN3, AC022098.2, IL27RA, PALM3, EEF1DP1, MISP3, MIR1199, C19orf67, SAMD1, PRKACA, AC022098.3, ASF1B, AC022098.1, ADGRL1, RN7SL231P.
- chr19:24,162,370–24,163,425, 1 gene, copy number 7: AC073534.1.

Autosomal genes at a single copy (total copy number 1): 288. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
